Somatic mutation profile of tumor specimen 0DWVGP from CCDI case PBCPMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 16.1 years (5,866 days).
Specimen 0DWVGP: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64d3bddc-1e18-4406-a409-6e879b6547af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d93656a8-9012-49ae-9c0d-2e0f49befccf

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CORO1C | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 96/261 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as COSV54594899; called by muse, mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- PARD6A | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs771559899; called by muse, mutect2, varscan2
- COL7A1 | c.6053G>T p.G2018V | Missense Mutation (SNP) | VAF 39/515 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EFCAB5 | c.818G>T p.S273I | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GLDN | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SAMD12 | c.560T>A p.L187* | Nonsense Mutation (SNP) | VAF 116/241 reads (48%) | called by muse, mutect2, varscan2
- SERPINA11 | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 140/307 reads (46%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGSM1 | c.3434T>A p.I1145N (on ENST00000400359 / NM_001039948.4; = p.I1084N on NM_133454.3) | Missense Mutation (SNP) | VAF 89/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMC1A | c.138C>G p.S46R | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRAME | c.1476C>T p.D492= | Silent (SNP) | VAF 128/329 reads (39%) | called by muse, mutect2, varscan2
- THUMPD2 | c.447A>C p.I149= | Silent (SNP) | VAF 42/366 reads (11%) | called by muse, mutect2, varscan2
- GUCY2D | c.2769+73C>T | Intron (SNP) | VAF 43/98 reads (44%) | catalogued as rs1209494235; called by muse, mutect2, varscan2
- SNPH | c.-47-170C>A | Intron (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
